Somatic mutation profile of tumor specimen 0DOXH0 from CCDI case PBCCZM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 18.1 years (6,621 days).
Specimen 0DOXH0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bedaf26-1878-4cb6-81d0-8ee348b789c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOXG3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d9d2ead-dd42-4ecb-875e-e15e4967fe39

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 2, 3'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC018630.4 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 61/150 reads (41%) | catalogued as rs771692134; called by muse, mutect2, varscan2
- DGKD | c.533A>G p.N178S (on ENST00000264057 / NM_152879.3; = p.N134S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/357 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs770550183; called by muse, mutect2, varscan2
- SRCAP | c.5633dup p.P1879Tfs*21 | Frame Shift Ins (INS) | VAF 44/161 reads (27%) | catalogued as rs748467821; called by mutect2, varscan2
- WASHC4 | c.2767A>G p.M923V | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs779313558, COSV59890542; called by muse, mutect2, varscan2
- BICD1 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 177/419 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DNAJC16 | c.1909C>A p.L637I | Missense Mutation (SNP) | VAF 165/387 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DPP6 | c.938T>A p.L313H (on ENST00000377770 / NM_001364500.2; = p.L251H on NM_001936.5) | Missense Mutation (SNP) | VAF 156/326 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAREM2 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MIER3 | c.653_654insG p.K219* | Frame Shift Ins (INS) | VAF 158/409 reads (39%) | called by mutect2, varscan2
- OR5L1 | c.695A>G p.E232G | Missense Mutation (SNP) | VAF 132/347 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- AR | c.2220C>T p.Y740= | Silent (SNP) | VAF 165/347 reads (48%) | catalogued as rs1317957783, COSV65960132; called by muse, mutect2, varscan2
- H2BC18 | c.27T>C p.P9= | Silent (SNP) | VAF 160/452 reads (35%) | called by muse, mutect2, varscan2
- CLUAP1 | c.1092+241A>G | Intron (SNP) | VAF 48/134 reads (36%) | called by mutect2, varscan2
- PRDM12 | c.*11G>A | 3'UTR (SNP) | VAF 3/25 reads (12%) | called by muse, varscan2
